Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3875, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3875-01A (Primary Tumor).

Diagnosis/ diagnoses

Right hemicolectomy preparation with a colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, located 6 cm from Bauhin's valve, and measuring a max of 2 cm in diameter. Invasive spreading of the tumor up to the level of the submucosa.

Appendix with postinflammatory fibrosis of the wall and fibrous apical obliteration.

Oral and aboral resection margins are tumor-free as is the greater omentum.

31 mesocolic and mesenteric lymph nodes are tumor-free with uncharacteristically reactive lesions.

Therefore the tumor stage is: pT1, pN0 (0/31) L0, V0; G2

Source: NCI Genomic Data Commons file e20bdbb0-641d-43fe-aa23-332c109e2a75 (TCGA-AA-3875.8E2D005B-0201-41EF-9118-15FA334B7CC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).